Gene-level copy-number profile of tumor specimen TCGA-DX-A2IZ-01A from TCGA case TCGA-DX-A2IZ, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 60.9 years (22,245 days).
Specimen TCGA-DX-A2IZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.28e4b286-ea1d-4f20-84ee-d8672d4127cf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A2IZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ef17f14b-9250-416b-8d00-bf21d86da6e3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,620; copy number 2: 47,528; copy number 3: 2,626; copy number 4: 24; copy number 5: 52; copy number 6: 15; copy number 7: 12; copy number 8: 52; copy number 9: 43; copy number 10: 238; copy number 11: 130; copy number 12: 37; copy number 13: 39; copy number 14: 86; copy number 15: 82; copy number 16: 19; copy number 17: 8; copy number 18: 66; copy number 19: 49; copy number 20: 58; copy number 21: 23; copy number 25: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A2IZ-01A-11D-A21P-01): tumor purity 0.94, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,014 genes in 57 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:56,994,778–58,546,734, 3 genes, copy number 9 (within-gene range 2–15): DAB1, AL390243.1, RPS20P5.
- chr1:58,047,889–60,149,784, 33 genes, copy number 5–14: HNRNPA1P6, RPS26P15, AL445193.2, AL445193.1, AL357373.1, OMA1, AL035411.3, AL035411.2, RN7SL713P, TACSTD2, AL035411.1, MYSM1, AL136985.3, JUN, LINC01135, AL136985.2, AL136985.1, LINC02777, LINC01358, PHBP3, AL592431.2, AL592431.1, HSD52, AC093424.1, FGGY, MIR4711, AL035416.1, HOOK1, CYP2J2, RN7SL475P, C1orf87, PGBD4P8, LINC02778.
- chr1:60,865,259–62,178,675, 12 genes, copy number 9 (within-gene range 2–9): NFIA, NFIA-AS2, NFIA-AS1, AC099791.3, AC099791.4, AC099791.1, TM2D1, AC099791.2, PATJ, RNU6-414P, RNU6-1177P, LAMTOR5P1.
- chr1:62,189,131–62,319,434, 7 genes, copy number 6: PIGPP2, RPS15AP7, L1TD1, AL162739.1, Y_RNA, KANK4, RNU6-371P.
- chr5:191,495–667,168, 22 genes, copy number 10 (within-gene range 2–10): LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72.
- chr5:1,173,141–2,184,820, 36 genes, copy number 14: CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, AC026748.7, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2, AC026412.4, MIR4277, AC112176.1, MRPL36, NDUFS6, AC025183.1, LINC02116, AC025183.2, IRX4, IRX4-AS1, CTD-2194D22.4, AC126768.3, AC124852.1, AC126768.1, AC126768.2, Y_RNA.
- chr5:8,012,377–8,366,437, 5 genes, copy number 10: AC116361.1, AC091941.1, AC091912.2, AC091912.1, AC091912.3.
- chr5:9,363,275–9,903,852, 11 genes, copy number 7 (within-gene range 2–7): AC091906.1, AC027335.2, SEMA5A-AS1, AC027335.1, SNHG18, SNORD123, AC026787.1, TAS2R1, LINC02112, RNA5SP177, AC091838.1.
- chr5:10,225,507–10,522,084, 19 genes, copy number 5–9: ATPSCKMT, AC012640.1, CCT5, AC012640.4, AC012640.3, CMBL, Y_RNA, Y_RNA, AC012640.5, AC012640.2, MARCHF6, ROPN1L-AS1, ROPN1L, MIR6131, LINC01513, RPL30P7, AC092336.1, LINC02212, LINC02213.
- chr5:15,425,758–15,939,795, 4 genes, copy number 10–19 (within-gene range 1–19): AC114964.2, AC114964.1, FBXL7, CTD-2350J17.1.
- chr5:16,473,038–18,236,196, 56 genes, copy number 14–20 (within-gene range 1–20): RETREG1, AC024588.1, AC022113.1, Y_RNA, MYO10, RNA5SP179, RPS26P28, RNU6-660P, BASP1, BASP1-AS1, AC026790.1, Y_RNA, RNA5SP180, DCAF13P2, RNU6-1003P, AC026785.1, RN7SKP133, FTH1P10, AC026785.2, AC026785.3, LINC02111, LINC02217, LINC02218, H3Y2, AC106774.1, TAF11L2, H3P17, H3P18, TAF11L3, TAF11L4, TAF11L5, TAF11L6, TAF11L7, AC233724.7, TAF11L8, TAF11L9, TAF11L10, AC233724.3, AC233724.6, TAF11L11, TAF11L12, H3P19, H3P20, H3P21, TAF11L13, TAF11L14, AC233724.4, AC233724.1, AC233724.5, AC233724.2, H3Y1, AC233724.8, H3P22, LINC02223, RPL36AP21, SNORD81.
- chr5:18,886,622–18,958,413, 4 genes, copy number 25: UBE2V1P12, AC025768.1, AC114981.1, Metazoa_SRP.
- chr5:22,139,247–24,353,443, 20 genes, copy number 9–14 (within-gene range 1–14): AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1, AC108103.1, C5orf17, AC026784.1, ADH5P5, Y_RNA, AC114930.1, AC010342.1, AC010387.1.
- chr5:28,213,359–30,743,704, 28 genes, copy number 8–11: AC093300.1, LINC02103, AC008825.1, AC109472.1, RNU6-909P, AC008825.2, LINC02109, AC010385.2, LSP1P3, AC010385.1, AC010385.3, SUCLG2P4, AC024589.2, AC024589.1, AC024589.3, AC112172.2, LINC02064, AC027345.1, UBL5P1, AC108082.1, AC010374.2, AC010374.1, RN7SKP207, AC018765.1, HPRT1P2, AC114300.1, AC099517.1, AC026433.1.
- chr5:31,093,977–31,532,196, 5 genes, copy number 5 (within-gene range 2–5): AC113386.1, CDH6, DUX4L51, DROSHA, Y_RNA.
- chr5:39,571,478–40,053,324, 4 genes, copy number 8 (within-gene range 3–8): CCDC11P1, INTS6P1, GCSHP1, LINC00603.
- chr12:49,265,156–49,337,188, 5 genes, copy number 6: AC125611.3, AC125611.4, PRPH, TROAP, C1QL4.
- chr12:53,816,185–53,985,519, 11 genes, copy number 15: RN7SKP289, HOXC13-AS, HOXC13, HOXC12, HOTAIR, AC012531.5, AC012531.7, AC012531.4, AC012531.6, HOXC11, HOXC-AS3.
- chr12:54,830,518–55,284,641, 13 genes, copy number 15 (within-gene range 1–15): MUCL1, TESPA1, AC027287.2, NEUROD4, OR9K1P, AC027287.1, OR9K2, OR9R1P, OR10U1P, OR10A7, OR6C74, OR6C69P, OR6C72P.
- chr12:55,411,727–56,874,268, 102 genes, copy number 11–20 (within-gene range 1–20) (broad region; genes not listed).
- chr12:57,128,483–58,920,504, 68 genes, copy number 11–18 (within-gene range 1–18) (broad region; genes not listed).
- chr12:61,708,259–62,279,150, 5 genes, copy number 17 (within-gene range 1–17): TAFA2, RPL21P104, KRT8P19, RPS3P6, AC078789.1.
- chr12:65,758,020–66,170,072, 13 genes, copy number 16 (within-gene range 1–16): RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4.
- chr12:67,065,018–68,332,381, 24 genes, copy number 19 (within-gene range 4–19): AC073530.2, RAB11AP2, GGTA2P, CAND1, AC078983.1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1.
- chr12:68,552,995–68,671,901, 5 genes, copy number 16 (within-gene range 3–22): RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G.
- chr12:68,686,951–69,584,823, 26 genes, copy number 8–21 (within-gene range 3–21): NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2.
- chr12:69,825,227–70,434,292, 8 genes, copy number 9–12 (within-gene range 1–12): MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4.
- chr12:71,582,293–72,670,758, 18 genes, copy number 8–13 (within-gene range 1–13): AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1, TRHDE, TRHDE-AS1, H3P35.
- chr12:73,115,957–73,208,317, 3 genes, copy number 11–25: AC090503.2, LINC02444, AC090503.1.
- chr12:74,170,445–74,293,096, 4 genes, copy number 14: AC090502.3, AC090502.2, AC090502.1, VENTXP3.
- chr12:94,140,077–94,307,675, 6 genes, copy number 15: AC123567.1, PLXNC1, AC123567.2, AC073655.3, AC073655.1, AC073655.2.
- chr12:100,173,196–101,128,641, 13 genes, copy number 11–13 (within-gene range 1–13): AC010203.1, MIR1827, ACTR6, DEPDC4, Y_RNA, SCYL2, SLC17A8, NR1H4, AC010200.1, GAS2L3, PIGAP1, ANO4, AC138360.1.
- chr12:101,155,493–101,386,618, 4 genes, copy number 12: SLC5A8, RNU6-768P, AC079953.1, UTP20.
- chr12:101,475,336–102,463,491, 28 genes, copy number 9–19 (within-gene range 1–19): SPIC, MYBPC1, AC117505.1, AC010205.1, CHPT1, SYCP3, GNPTAB, RNU6-101P, AC063950.1, RNA5SP368, RNU6-172P, RNA5SP369, RNU6-1183P, HSPE1P4, DRAM1, AC084398.2, AC084398.1, AC079907.2, NENFP2, WASHC3, AC079907.1, NUP37, PARPBP, PMCH, HELLPAR, RN7SL793P, AC093023.1, LINC02456.
- chr12:103,237,591–104,762,014, 33 genes, copy number 9–14 (within-gene range 1–14): C12orf42, AC084364.1, AC084364.2, AC084364.3, LINC02401, STAB2, U8, AC025265.2, AC025265.3, AC025265.1, NT5DC3, AC012555.2, AC012555.1, TTC41P, HSP90B1, MIR3652, C12orf73, TDG, GLT8D2, AC078819.1, HCFC2, NFYB, RNA5SP370, LINC02385, AC089983.2, TXNRD1, AC089983.1, RPL18AP3, EID3, CHST11, AC079316.1, AC079316.2, MIR3922.
- chr12:125,958,688–126,191,406, 7 genes, copy number 15: LINC00939, LINC02826, LINC02359, AC005858.2, AC005858.3, AC005858.1, AC005888.1.
- chr12:126,610,034–127,486,675, 27 genes, copy number 15: AC006065.4, AC006065.2, AC006065.3, AC006065.5, AC006065.6, LINC02824, LINC00943, LINC00944, AC078878.1, LINC02372, AC078878.2, HSPE1P20, LINC02405, AC079949.3, AC079949.1, AC079949.5, AC079949.2, AC079949.6, LINC02376, AC073913.1, RNU1-104P, LINC02375, AC073913.2, AC048347.1, AC068787.4, AC068787.1, AC068787.3.
- chr14:94,487,274–99,272,197, 92 genes, copy number 6–13 (within-gene range 2–13) (broad region; genes not listed).
- chr14:100,207,407–101,927,989, 160 genes, copy number 10 (within-gene range 2–10) (broad region; genes not listed).
- chr14:102,317,377–103,562,831, 46 genes, copy number 5–15: ZNF839, CINP, TECPR2, RNU6-244P, ANKRD9, MIR4309, LINC02323, RN7SL546P, RCOR1, RPL23AP11, Y_RNA, AL132801.1, TRAF3, RNU6-1316P, AMN, CDC42BPB, AL117209.1, RPL13P6, LBHD2, AL161669.1, EXOC3L4, AL161669.4, LINC00677, TNFAIP2, NDUFB4P11, RPL21P12, GCSHP2, LINC00605, AL161669.2, AL161669.3, RPL21P13, RAP2CP1, AL138976.1, AL138976.2, EIF5, SNORA28, HMGB3P26, RPSAP5, MARK3, RPL10AP1, CKB, AL133367.1, TRMT61A, RNU7-160P, AL139300.2, BAG5.

Autosomal genes at a single copy (total copy number 1): 6,199. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
